Somatic mutation profile of tumor specimen TCGA-UZ-A9PV-01A (aliquot TCGA-UZ-A9PV-01A-11D-A42J-10) from TCGA case TCGA-UZ-A9PV, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I.
Specimen TCGA-UZ-A9PV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e4767440-2922-4644-afab-76b87c73fcf5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UZ-A9PV-10A (Blood Derived Normal), aliquot TCGA-UZ-A9PV-10A-01D-A42M-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c483616-b656-450a-b905-5effcc956cf5

The open-access MAF lists 61 somatic variants for this specimen: 48 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 37, Silent 13, Frame Shift Del 6, Nonsense Mutation 3, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.2354G>A p.R785H | Missense Mutation (SNP) | VAF 54/95 reads (57%) | SIFT tolerated (0.47); PolyPhen benign (0.022); catalogued as rs368457541; called by muse, mutect2, varscan2
- ACACA | c.4209G>T p.E1403D | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); catalogued as rs1436436514; called by muse, mutect2, varscan2
- AGPAT1 | c.161C>A p.P54H | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV100421626; called by muse, mutect2, varscan2
- ALX3 | c.835G>T p.G279W | Missense Mutation (SNP) | VAF 62/133 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100873878; called by muse, mutect2, varscan2
- ASTE1 | c.632A>T p.N211I | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99393801; called by muse, mutect2, varscan2
- C11orf24 | c.25del p.W9Gfs*29 | Frame Shift Del (DEL) | VAF 19/48 reads (40%) | catalogued as rs1159924603; called by mutect2, pindel, varscan2
- CACNA1A | c.2608G>C p.D870H | Missense Mutation (SNP) | VAF 128/271 reads (47%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.667); catalogued as COSV100802381, COSV100803604, COSV64199682; called by muse, mutect2, varscan2
- CDHR2 | c.2005G>A p.D669N | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56141111; called by muse, mutect2, varscan2
- CEP57 | c.1313A>G p.K438R | Missense Mutation (SNP) | VAF 98/200 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100334702; called by muse, mutect2, varscan2
- DNAJC24 | c.327C>A p.H109Q | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV99540935; called by muse, mutect2, varscan2
- DYNC1H1 | c.1860C>G p.H620Q | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.614); catalogued as COSV100794849; called by muse, mutect2
- DYNC2H1 | c.10448T>A p.I3483N | Missense Mutation (SNP) | VAF 49/92 reads (53%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV100518493; called by muse, mutect2, varscan2
- EXPH5 | c.1245T>A p.Y415* | Nonsense Mutation (SNP) | VAF 39/76 reads (51%) | catalogued as COSV99761582; called by muse, mutect2, varscan2
- FER1L6 | c.2764G>A p.V922I | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated (0.45); PolyPhen benign (0.018); catalogued as COSV101205823; called by muse, mutect2, varscan2
- FOXO4 | c.220C>A p.P74T | Missense Mutation (SNP) | VAF 110/112 reads (98%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as COSV100446905; called by muse, mutect2, varscan2
- GRXCR2 | c.340C>A p.L114I | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as COSV100939988; called by muse, mutect2, varscan2
- HECW1 | c.2386A>G p.N796D | Missense Mutation (SNP) | VAF 127/220 reads (58%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as COSV101223470; called by muse, mutect2, varscan2
- HERC6 | c.156G>C p.R52S | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT tolerated (0.34); PolyPhen benign (0.193); catalogued as rs1462258189, COSV99910545; called by muse, mutect2, varscan2
- LHX5 | c.6G>A p.M2I | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.177); catalogued as COSV99922463; called by muse, mutect2, varscan2
- LOXL1 | c.1607A>C p.H536P | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.303); catalogued as rs1314503570, COSV99985308; called by muse, mutect2, varscan2
- MARCHF3 | c.79G>C p.V27L | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.006); catalogued as COSV100427828; called by muse, mutect2, varscan2
- MED10 | c.386G>T p.G129V | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs145638352; called by muse, mutect2, varscan2
- MRFAP1 | c.116T>C p.I39T | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.158); catalogued as COSV100307626; called by muse, mutect2, varscan2
- NUDT21 | c.455A>T p.N152I | Missense Mutation (SNP) | VAF 81/155 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100295599; called by muse, mutect2, varscan2
- OOEP | c.314G>T p.R105L | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as rs199988719, COSV100949821; called by muse, mutect2, varscan2
- OR1A1 | c.693G>T p.K231N | Missense Mutation (SNP) | VAF 62/87 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100410758; called by muse, mutect2, varscan2
- OR2T33 | c.385C>T p.R129* | Nonsense Mutation (SNP) | VAF 26/428 reads (6%) | catalogued as rs1396360611, COSV100531888; called by muse, mutect2
- PLA2G4F | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs144626679; called by muse, mutect2, varscan2
- RASEF | c.754A>G p.K252E | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as COSV100906866; called by muse, mutect2, varscan2
- ROS1 | c.2938G>C p.V980L | Missense Mutation (SNP) | VAF 97/203 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV100877038; called by muse, mutect2, varscan2
- SLC13A4 | c.4G>T p.G2C | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as COSV100647278; called by muse, mutect2, varscan2
- SLC4A4 | c.524A>T p.E175V (on ENST00000264485 / NM_001098484.3; = p.E131V on NM_003759.4) | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.901); catalogued as rs1232716865, COSV99140107; called by muse, mutect2, varscan2
- SMG6 | c.2629G>A p.E877K | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.251); catalogued as COSV99558151; called by muse, mutect2, varscan2
- TULP3 | c.32G>A p.S11N | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.017); catalogued as COSV100817041; called by muse, mutect2, varscan2
- VILL | c.1237C>G p.Q413E | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.685); catalogued as COSV99378778; called by muse, mutect2, varscan2
- WASL | c.1400T>C p.I467T | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.345); catalogued as COSV99771635; called by muse, mutect2, varscan2
- WDR25 | c.545G>T p.R182I | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100091767; called by muse, mutect2, varscan2
- WWTR1 | c.916C>T p.H306Y | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV62291571; called by muse, mutect2, varscan2
- ZNF335 | c.2867G>T p.G956V | Missense Mutation (SNP) | VAF 55/80 reads (69%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV100532961; called by muse, mutect2, varscan2
- BPTF | c.6064dup p.E2022Gfs*7 | Frame Shift Ins (INS) | VAF 58/121 reads (48%) | called by mutect2, pindel, varscan2
- CAMK4 | c.699del p.L234Yfs*22 | Frame Shift Del (DEL) | VAF 6/55 reads (11%) | called by mutect2, pindel, varscan2
- KCNN1 | c.1034_1038del p.G345Vfs*29 | Frame Shift Del (DEL) | VAF 14/32 reads (44%) | called by mutect2, pindel, varscan2
- LGR4 | c.324dup p.V109Sfs*7 | Frame Shift Ins (INS) | VAF 78/193 reads (40%) | called by mutect2, pindel, varscan2
- RAB29 | c.392C>A p.P131H | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.225); called by muse, mutect2
- VWF | c.8054del p.F2685Sfs*25 | Frame Shift Del (DEL) | VAF 28/79 reads (35%) | called by mutect2, pindel, varscan2
- ZNF639 | c.1137_1174del p.C379* | Nonsense Mutation (DEL) | VAF 26/199 reads (13%) | called by mutect2, pindel
- ZNF792 | c.440del p.L147Wfs*20 | Frame Shift Del (DEL) | VAF 41/99 reads (41%) | called by mutect2, pindel, varscan2
- ZPLD1 | c.882_883del p.H295Lfs*10 (on ENST00000466937 / NM_001329788.1; = p.H311Lfs*10 on NM_175056.2) | Frame Shift Del (DEL) | VAF 37/77 reads (48%) | called by mutect2, pindel, varscan2
- CEMIP | c.3366C>T p.S1122= | Silent (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- CLCN3 | c.444T>A p.I148= | Silent (SNP) | VAF 32/62 reads (52%) | catalogued as COSV100641708; called by muse, mutect2, varscan2
- CNOT3 | c.270G>C p.R90= | Silent (SNP) | VAF 54/118 reads (46%) | catalogued as COSV55368846, COSV99651822; called by muse, mutect2, varscan2
- DPH5 | c.666A>G p.L222= | Silent (SNP) | VAF 35/80 reads (44%) | catalogued as COSV100587394; called by muse, mutect2, varscan2
- FBL | c.561C>T p.V187= | Silent (SNP) | VAF 39/82 reads (48%) | catalogued as rs982425093, COSV99695283; called by muse, mutect2, varscan2
- FOXL1 | c.174C>A p.I58= | Silent (SNP) | VAF 76/179 reads (42%) | catalogued as COSV100206230, COSV57213736; called by muse, mutect2, varscan2
- GPAT3 | c.753T>C p.H251= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as COSV100023011; called by muse, mutect2, varscan2
- LVRN | c.2712C>G p.V904= | Silent (SNP) | VAF 63/116 reads (54%) | catalogued as COSV100773445, COSV100773713; called by muse, mutect2, varscan2
- MAGEC1 | c.2202G>A p.E734= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs1198534420, COSV53568922; called by muse, mutect2
- MRPL37 | c.600G>A p.R200= | Silent (SNP) | VAF 39/80 reads (49%) | catalogued as COSV100289205; called by muse, mutect2, varscan2
- PTPRB | c.651T>C p.I217= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as COSV100547191; called by muse, mutect2, varscan2
- SCN9A | c.5241C>A p.S1747= (on ENST00000303354; = p.S1736= on NM_002977.3) | Silent (SNP) | VAF 46/103 reads (45%) | catalogued as COSV57608742; called by muse, mutect2, varscan2
- TXLNB | c.2049C>A p.V683= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as COSV100624936; called by muse, mutect2, varscan2
